Surgical pathology report (de-identified scan), TCGA case TCGA-K7-A5RG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K7-A5RG-01A (Primary Tumor).

[page 1 of 3]
Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status Final

Results

Source of Specimen
SEGMENT 7 OF LIVER-

ICD-0-3
Carcinoma, hepatocellular, NOS 8170/3 Final
Site: liver C22.0 lw
2/17/13

FINAL DIAGNOSIS:
SEGMENT 7 OF LIVER-
INVASIVE CARCINOMA, SOLITARY, CONFINED TO LIVER.

HISTOLOGIC TYPE: HEPATOCELLULAR.

HISTOLOGIC GRADE: 1/4.

TUMOR LOCATION: SEGMENT 7 OF LIVER.

TUMOR SIZE: 3.5 x 3.5 x 3.5 CM.

LYMPH-VASCULAR INVASION:

MACROSCOPIC VENOUS INVASION: IS NOT PRESENT.

MICROSCOPIC SMALL VESSEL/LYMPHATIC INVASION: IS NOT PRESENT.

TNM STAGE: pT1, pNX, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER EXAMINED: 0

PRE-TRANSPLANT TREATMENT FOR HCC: NO

SATELLITE LESIONS: ARE NOT PRESENT.

TUMOR NECROSIS: INCOMPLETE 10 (%)

Prepared

[page 2 of 3]
SPECIMEN TYPE: SEGMENTECTOMY

SPECIMEN SIZE: 9 x 7 x 3.5 CM.

UNOS HCC STAGE: STAGE 2.

TIPS: NO

OTHER FINDINGS:

LARGE CELL CHANGE AND DUCTAL DYSPLASIA ARE PRESENT.

CIRRHOSIS/FIBROSIS: IS PRESENT.

IRON STAINING : IS PRESENT. TRACE IN HEPATOCYTES TRACE IN
KUPFFER CELLS. (IRON, TRICHROME AND RETICULIN STAINS EXAMINED).

HEPATITIS: IS PRESENT. GRADE 2/4.

MARGINS: THE TUMOR EXTENDS TO 0.7 CM FROM RESECTION MARGIN.

RETICULIN STAIN OF TUMOR (SLIDE A2) AND OF NON-NEOPLASTIC LIVER
(A6) EXAMINED.

Comment

Appropriate internal and/or external positive controls were
stained along side sections from this case. The control tissue
was examined and judged to be technically acceptable.

Signature

(Case signed

Case Clinical Information
HEPATOCELLULAR CARCINOMA

Gross Description

Received in formalin labeled with the patient's name and
"segment 7 of liver" is a segment of liver weighing 100 grams
and measuring 9 x 7 x 3.5 cm. The resection margin has been
previously inked black. The specimen is serially sectioned
showing a grey-tan firm nodular mass measuring 3.5 x 3.5 x 3.5
cm located 0.7 cm from the inked resection margin. The
remainder of the parenchyma is grey-brown and no other lesion is
grossly identified. The specimen is represented as follows:
tumor to the inked resection margin in A1-A4; tumor cross
section in A5; parenchyma away from the lesion in A6

Prepared

[page 3 of 3]
Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1 RETIC
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1 FE RETIC TRICHROME

Prepared

Criteria	10/26/13	Yes	No
Dual/Sync. Ironous Primary Noted			/

Source: NCI Genomic Data Commons file c8122175-2cd7-47d7-a452-82c5e919096d (TCGA-K7-A5RG.AADEAE33-3867-4F77-AAA6-072471B5A397.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).